Somatic mutation profile of tumor specimen TCGA-YC-A9TC-01A (aliquot TCGA-YC-A9TC-01A-22D-A391-08) from TCGA case TCGA-YC-A9TC, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 72.0 years (26,283 days).
Specimen TCGA-YC-A9TC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efd96746-d1c8-441b-a1f6-9d7ae44b8813.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YC-A9TC-10A (Blood Derived Normal), aliquot TCGA-YC-A9TC-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a98ce22-27b6-4f35-a4f0-1ed33b530a67

The open-access MAF lists 129 somatic variants for this specimen: 103 protein-altering or splice-affecting, 22 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 22, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 2, Intron 2, Splice Site 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 43/95 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.13450C>T p.R4484* | Nonsense Mutation (SNP) | VAF 22/89 reads (25%) | catalogued as rs587783690, CM111921, COSV56434635; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.85G>C p.D29H | Missense Mutation (SNP) | VAF 55/70 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519920, COSV67960002, COSV67960389, COSV67960852; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACSM6 | c.792G>A p.W264* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as COSV100498965; called by muse, mutect2, varscan2
- ANXA7 | c.1005G>C p.Q335H (on ENST00000372919 / NM_001320880.2; = p.Q313H on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV65823423; called by muse, varscan2
- APC | c.7546G>C p.E2516Q | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.614); catalogued as COSV57341745; called by muse, mutect2, varscan2
- ARCN1 | c.340G>C p.D114H | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50614885; called by muse, mutect2, varscan2
- ARID4B | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as COSV51602597, COSV51611202; called by muse, mutect2, varscan2
- ATM | c.8916G>C p.Q2972H | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV53741504; called by muse, mutect2, varscan2
- ATP2B2 | c.1868+1G>T p.X623_splice (on ENST00000352432; = p.X589_splice on NM_001683.5) | Splice Site (SNP) | VAF 26/75 reads (35%) | catalogued as rs1435277486, COSV59495500; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1826A>G p.H609R | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV63244940; called by muse, mutect2, varscan2
- BRDT | c.2803C>T p.Q935* | Nonsense Mutation (SNP) | VAF 40/109 reads (37%) | catalogued as COSV100746292; called by muse, mutect2, varscan2
- CASP9 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61601397; called by muse, mutect2, varscan2
- CEMIP2 | c.3040G>A p.E1014K | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV65484509; called by muse, mutect2, varscan2
- CFAP65 | c.4526C>T p.S1509F | Missense Mutation (SNP) | VAF 44/60 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV100445944, COSV58560589; called by muse, mutect2, varscan2
- CNTN6 | c.1924G>T p.G642C | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755176157, COSV63170954; called by muse, mutect2, varscan2
- COL15A1 | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.095); catalogued as rs77414605; called by muse, varscan2
- CSF3R | c.1404dup p.S469Qfs*5 | Frame Shift Ins (INS) | VAF 26/70 reads (37%) | catalogued as rs747437399; called by mutect2, varscan2
- CSMD1 | c.2313G>T p.L771F (on ENST00000520002; = p.L770F on NM_033225.6) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59317812; called by muse, mutect2, varscan2
- CYTL1 | c.268G>C p.D90H | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); catalogued as COSV57036737; called by muse, mutect2, varscan2
- DCAF12L1 | c.349T>C p.C117R | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64421720; called by muse, mutect2, varscan2
- DYNC1H1 | c.8275A>T p.I2759F | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as COSV64136563; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2578C>T p.R860C | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs1187952369, COSV62567667; called by muse, mutect2, varscan2
- EEF2 | c.1190A>G p.Y397C | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58579308; called by muse, mutect2, varscan2
- ESYT1 | c.621C>G p.I207M | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV57272710, COSV57273097; called by muse, varscan2
- ETNPPL | c.1451G>C p.G484A | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.193); catalogued as COSV56595616; called by muse, mutect2, varscan2
- FAM155A | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1566511581, COSV101027566; called by mutect2, varscan2
- FAT2 | c.8005C>G p.P2669A | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55818869, COSV55829025; called by muse, mutect2, varscan2
- GABPA | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as rs1416818876, COSV61396134; called by muse, mutect2, varscan2
- GANC | c.2544G>C p.Q848H | Missense Mutation (SNP) | VAF 38/79 reads (48%) | PolyPhen benign (0); catalogued as COSV58808767; called by muse, mutect2, varscan2
- GIMAP7 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.659); catalogued as rs367811003, COSV57959292; called by muse, mutect2, varscan2
- GPR171 | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.832); catalogued as COSV56377535; called by muse, mutect2, varscan2
- HEG1 | c.818C>T p.T273M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs752055512, COSV60761626; called by muse, mutect2, varscan2
- ICE2 | c.318G>C p.R106S | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV55031174; called by muse, mutect2, varscan2
- INIP | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.26); catalogued as COSV65295422; called by muse, mutect2, varscan2
- KCNH1 | c.1370C>T p.T457I (on ENST00000271751 / NM_172362.3; = p.T430I on NM_002238.4) | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV55079905; called by muse, mutect2, varscan2
- KCNMA1 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as COSV54245483; called by muse, mutect2, varscan2
- KRT76 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as rs759331306, COSV60120089; called by muse, mutect2, varscan2
- KRT9 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV55852922, COSV99879091; called by muse, mutect2, varscan2
- LHCGR | c.370C>G p.R124G | Missense Mutation (SNP) | VAF 91/214 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.487); catalogued as rs773279269, COSV54294553, COSV54296553; called by muse, mutect2, varscan2
- LPGAT1 | c.381G>C p.L127F | Missense Mutation (SNP) | VAF 69/138 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV65351494; called by muse, mutect2, varscan2
- LUC7L | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV53458214; called by muse, mutect2, varscan2
- MPDZ | c.3254A>C p.K1085T | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV59917500; called by muse, mutect2, varscan2
- MRE11 | c.1238A>G p.N413S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.634); catalogued as rs587782457, COSV60576478; ClinVar: uncertain significance; called by muse, mutect2
- MYO18A | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.243); catalogued as COSV62865930; called by mutect2, varscan2
- MYO9B | c.3390G>C p.Q1130H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV68278808; called by muse, varscan2
- MYO9B | c.3516G>C p.E1172D | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs370689291; called by muse, varscan2
- MYO9B | c.3598G>A p.D1200N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.657); catalogued as COSV68278821; called by muse, varscan2
- NISCH | c.4135G>A p.E1379K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs750243875, COSV58735590; called by muse, mutect2, varscan2
- NLRP14 | c.1903G>T p.V635L | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as rs1285611941, COSV55066735; called by muse, mutect2, varscan2
- NONO | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 45/56 reads (80%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.063); catalogued as COSV52137355; called by muse, mutect2, varscan2
- NSUN2 | c.1083C>G p.I361M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.1); catalogued as rs375801396; called by muse, mutect2, varscan2
- OR5D14 | c.746C>A p.S249Y | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as rs573879557, COSV59456144; called by muse, mutect2, varscan2
- OR7D4 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as rs1568329276, COSV58071636; called by muse, mutect2, varscan2
- PARP12 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 32/91 reads (35%) | catalogued as COSV99693995; called by muse, mutect2, varscan2
- PCDHA3 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65366692; called by muse, mutect2, varscan2
- PFKFB3 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | PolyPhen probably damaging (0.981); catalogued as COSV57988450; called by muse, mutect2, varscan2
- PHLDA1 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); catalogued as COSV56997257; called by muse, mutect2, varscan2
- PI4KB | c.502C>T p.R168C (on ENST00000368873 / NM_001369623.1; = p.R180C on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/175 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as rs750868780, COSV55017083; called by muse, mutect2, varscan2
- PLEKHA8 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV99321663; called by muse, mutect2, varscan2
- PRR23B | c.222C>A p.D74E | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.481); catalogued as COSV61493268, COSV61493598; called by muse, mutect2, varscan2
- PTEN | c.1114A>G p.N372D | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.393); catalogued as COSV100910093; called by muse, mutect2, varscan2
- PTGFRN | c.1787T>G p.L596R | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.172); catalogued as COSV67798395; called by muse, mutect2, varscan2
- PTPRD | c.4631C>A p.P1544H | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV61942853, COSV61995865; called by muse, mutect2, varscan2
- REXO1 | c.2873T>G p.F958C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.354); catalogued as COSV50077424; called by muse, mutect2, varscan2
- SBNO1 | c.2303C>G p.S768C (on ENST00000420886; = p.S767C on NM_018183.5) | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.662); catalogued as COSV57339188; called by muse, mutect2, varscan2
- SERAC1 | c.1600C>T p.H534Y | Missense Mutation (SNP) | VAF 118/296 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs925991264, COSV65596451; called by muse, mutect2, varscan2
- SPAG17 | c.3277G>C p.E1093Q | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.935); catalogued as COSV60457946; called by muse, mutect2, varscan2
- SPINK5 | c.832C>G p.Q278E | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56253246; called by muse, mutect2, varscan2
- SPTB | c.6917C>T p.S2306F | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs1444221072, COSV55979738; called by muse, mutect2, varscan2
- SQSTM1 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as rs777501273, COSV62434707; called by muse, mutect2, varscan2
- TEKT4 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.055); catalogued as rs781972423, COSV54624611; called by muse, mutect2, varscan2
- TEP1 | c.3241G>T p.G1081C | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1388490803, COSV52992034; called by muse, mutect2, varscan2
- TET2 | c.1249C>A p.Q417K | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.162); catalogued as COSV54401172, COSV54409356; called by muse, mutect2, varscan2
- THBS3 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs747277539, COSV57426532; called by muse, mutect2, varscan2
- TLR9 | c.1996G>T p.A666S | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as COSV62346581; called by muse, mutect2, varscan2
- TMEM236 | c.892G>C p.D298H | Missense Mutation (SNP) | VAF 125/304 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs976317974; called by muse, mutect2, varscan2
- TRIM59 | c.1044C>A p.F348L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV59087133; called by muse, mutect2, varscan2
- UGT2B11 | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 102/251 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV71423193, COSV71423301; called by muse, mutect2, varscan2
- UNC5B | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs779677077, COSV58976573; called by muse, mutect2, varscan2
- URI1 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs1193648880, COSV100368960; called by muse, mutect2
- USP34 | c.5048C>T p.S1683L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as COSV68400856; called by muse, varscan2
- USP8 | c.1695G>C p.K565N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV100208948; called by muse, mutect2
- VPS26C | c.438G>C p.Q146H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as rs762662868, COSV55706088; called by muse, mutect2, varscan2
- WDR26 | c.1255C>T p.H419Y (on ENST00000414423 / NM_001379403.1; = p.H319Y on NM_025160.7) | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1419548298, COSV54355137; called by muse, mutect2, varscan2
- WEE1 | c.767G>C p.R256T | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV55197054, COSV55197110; called by muse, mutect2, varscan2
- ZBTB7C | c.1274G>T p.C425F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs948021496, COSV59688601; called by muse, mutect2, varscan2
- ZFP69 | c.583G>C p.D195H | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV65528903; called by muse, mutect2, varscan2
- ZFPM2 | c.2525G>A p.R842Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs768561041, COSV65873063; called by muse, mutect2, varscan2
- ZNF225 | c.1772G>A p.G591D | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV53471554, COSV53472644; called by muse, mutect2, varscan2
- ZNF354A | c.669C>A p.F223L | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs755651031, COSV59983118; called by muse, varscan2
- ZNF638 | c.1387G>C p.D463H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52486516; called by muse, mutect2, varscan2
- ZNF709 | c.117C>G p.N39K | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67194665; called by muse, mutect2, varscan2
- ZNF808 | c.863A>G p.K288R | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as COSV63119669; called by muse, mutect2, varscan2
- ZNF808 | c.864G>T p.K288N | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63119673; called by muse, mutect2, varscan2
- ZSWIM8 | c.2038G>A p.E680K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV67132375; called by muse, mutect2, varscan2
- FAT1 | c.1912dup p.V638Gfs*38 | Frame Shift Ins (INS) | VAF 32/102 reads (31%) | called by mutect2, pindel, varscan2
- FBXW7 | c.896_912del p.K299Sfs*12 (on ENST00000281708 / NM_001349798.2; = p.K219Sfs*12 on NM_018315.5) | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by pindel, varscan2
- IDH1 | c.1126_1128delinsGT p.L376Vfs*17 | Frame Shift Del (DEL) | VAF 55/132 reads (42%) | called by pindel, varscan2*
- IGHV1-45 | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KMT2C | c.13666del p.H4556Tfs*70 | Frame Shift Del (DEL) | VAF 15/29 reads (52%) | called by mutect2, pindel, varscan2
- SSU72P8 | c.41G>A p.S14N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.261); called by muse, mutect2
- TRAV1-1 | c.59G>C p.S20T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ALDH8A1 | c.630C>A p.T210= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as rs544667948, COSV55641571; called by muse, mutect2, varscan2
- BCR | c.573C>G p.V191= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV59930784; called by muse, mutect2, varscan2
- CD93 | c.525T>C p.I175= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV55664806; called by muse, mutect2, varscan2
- CKMT1A | c.1179G>A p.L393= | Silent (SNP) | VAF 67/145 reads (46%) | catalogued as COSV63256801; called by muse, mutect2, varscan2
- FOXQ1 | c.447C>T p.L149= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV57258859; called by muse, mutect2, varscan2
- HPR | c.78C>A p.V26= | Silent (SNP) | VAF 38/130 reads (29%) | catalogued as COSV57182423; called by muse, mutect2, varscan2
- IPO5 | c.1740G>C p.V580= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV55154255; called by muse, mutect2, varscan2
- KCNV1 | c.504G>A p.K168= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV52085910; called by muse, mutect2, varscan2
- MCM7 | c.1872G>A p.V624= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as COSV57996180; called by muse, mutect2, varscan2
- NF1 | c.7770C>T p.H2590= (on ENST00000358273 / NM_001042492.3; = p.H2569= on NM_000267.3) | Silent (SNP) | VAF 47/190 reads (25%) | catalogued as rs1060503906, COSV62201897; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLCB2 | c.3381C>T p.Y1127= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as rs374674205; called by muse, mutect2, varscan2
- RASGRF1 | c.849C>T p.H283= | Silent (SNP) | VAF 48/117 reads (41%) | catalogued as rs181059534, COSV69178629; called by muse, mutect2, varscan2
- SERPINA7 | c.348C>T p.I116= | Silent (SNP) | VAF 53/74 reads (72%) | catalogued as COSV59665680; called by muse, mutect2, varscan2
- SMG1 | c.7912C>T p.L2638= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs1435489878, COSV101245703; called by muse, mutect2, varscan2
- STAB2 | c.7149C>T p.V2383= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as COSV66338494; called by muse, mutect2, varscan2
- SYNPO2 | c.1662C>T p.Y554= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs763941820, COSV61110146; called by muse, mutect2, varscan2
- TMC8 | c.933T>G p.V311= | Silent (SNP) | VAF 31/59 reads (53%) | catalogued as COSV59209499; called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.789C>G p.L263= | Silent (SNP) | VAF 81/195 reads (42%) | catalogued as COSV56695227, COSV56696414; called by muse, mutect2, varscan2
- TPO | c.759C>T p.F253= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs757051221, COSV61100942; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSC1 | c.2778G>A p.Q926= | Silent (SNP) | VAF 74/170 reads (44%) | catalogued as rs1554813423, COSV53766594; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.16722A>C p.G5574= (on ENST00000591111; = p.G4647= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 109/141 reads (77%) | catalogued as COSV60025462; called by muse, mutect2, varscan2
- ZNF354A | c.843C>T p.L281= | Silent (SNP) | VAF 66/166 reads (40%) | catalogued as COSV59983104; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500839 A>G | 5'Flank (SNP) | VAF 16/31 reads (52%) | catalogued as rs768801849; called by muse, mutect2, varscan2
- OBSCN | c.11660-2495C>T | Intron (SNP) | VAF 61/109 reads (56%) | catalogued as COSV52770303; called by muse, mutect2, varscan2
- OBSCN | c.18662-2097C>G | Intron (SNP) | VAF 4/17 reads (24%) | catalogued as COSV52809857, COSV99476583; called by muse, varscan2
- SNORD115-26 | n.5C>T | RNA (SNP) | VAF 90/252 reads (36%) | called by muse, mutect2, varscan2
